Somatic mutation profile of tumor specimen 0DQ80R from CCDI case PBCEIZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Schwannoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.1 years (3,701 days).
Specimen 0DQ80R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ea656b6-6a76-4e7e-8613-d91cd0595002.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ7WC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5e7b5c8-4bd1-4018-934f-696c09e2de84

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Splice Region 1, Silent 1, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RNF112 | c.588+5G>A | Splice Region (SNP) | VAF 38/386 reads (10%) | called by muse, mutect2
- SOX10 | c.513_521dup p.Y173_Q174insHKY | In Frame Ins (INS) | VAF 70/208 reads (34%) | called by mutect2, varscan2
- DZANK1 | c.303C>T p.H101= | Silent (SNP) | VAF 69/535 reads (13%) | catalogued as rs373925424; called by muse, mutect2, varscan2
- FLNA | c.*91C>T | 3'UTR (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
